Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A0TV, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A0TV-01A (Primary Tumor).

1C0-0-3

carcinoma, infiltrating ductal, NOS 8500/3
Site: breast, NOS C50.9

Breast, left, simple mastectomy: Infiltrating Nottingham grade III (of III) ductal carcinoma forming a 2.6 x 2.4 x 2.0 cm (AJCC pT2) mass located in the outer quadrant. No angiolymphatic invasion identified. No significant ductal carcinoma in situ component identified. A separate hyalinized fibroadenoma (1.2 x 1.0 x 1.0 cm) is present superior to the tumor mass. The nipple and skin are unremarkable.

Lymph nodes, left axillary sentinel, excision: Multiple (3) left axillary sentinel lymph nodes are negative for tumor. Blue dye is identified in left axillary sentinel lymph node No. 1. Blue dye is not identified in left axillary sentinel lymph nodes No. 2 and No. 3. Immunohistochemical cytokeratin stain was performed on the paraffin embedded sentinel lymph node tissue and confirms the H&E impression. [AJCCpN0(i-)]

Her-2/NEU has been ordered on paraffin embedded tissue.

Source: NCI Genomic Data Commons file 7f7b1b24-a317-489b-84dd-77d44f45502a (TCGA-AR-A0TV.7594A7F8-1806-4B74-99EF-4E4C889E7BEA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).